Somatic mutation profile of tumor specimen 59318d66-8b88-45b2-9b97-90e9a7 (aliquot 59318d66-8b88-45b2-9b97-90e9a7_D6_1) from CPTAC case 11BR072, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.6 years (25,793 days).
Specimen 59318d66-8b88-45b2-9b97-90e9a7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04fabf7e-7857-4559-82cc-b2a649ee3da0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen faa5e826-30db-411b-8f90-240c1f (Blood Derived Normal), aliquot faa5e826-30db-411b-8f90-240c1f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45e48003-4889-44d3-9b44-68b2e41bd7f3

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 38/165 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AK9 | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1025298490; called by muse, mutect2, varscan2
- CSNK1A1L | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 165/449 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65789602; called by muse, mutect2, varscan2
- CYP46A1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99952335; called by muse, mutect2, varscan2
- KRTAP10-10 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 148/564 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs376512849; called by muse, mutect2
- MEF2B | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 39/109 reads (36%) | catalogued as COSV50769044; called by muse, mutect2, varscan2
- MRGPRX1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 91/597 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs202061081; called by muse, mutect2, varscan2
- PARP12 | c.1498-1G>A p.X500_splice | Splice Site (SNP) | VAF 6/130 reads (5%) | catalogued as COSV99694155; called by muse, mutect2
- PITPNC1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs759328316, COSV55454518; called by muse, mutect2, varscan2
- ZNF804B | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60852608; called by muse, mutect2
- BAALC | c.461C>T p.A154V (on ENST00000297574 / NM_001364874.1; = p.A119V on NM_024812.3) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C1orf216 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 24/1044 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CADM3 | c.544G>A p.D182N (on ENST00000368125 / NM_001127173.3; = p.D216N on NM_021189.5) | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CIART | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 104/472 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CTNNA2 | c.1067A>T p.K356I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- FAM50A | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 26/275 reads (9%) | called by muse, mutect2
- GJB6 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- HRC | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- KRT34 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 173/653 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LAMA2 | c.5209A>C p.K1737Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MERTK | c.531G>T p.M177I | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2
- OR10K2 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 197/745 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEX6 | c.780_801delinsCCGCTGGG p.P261Rfs*15 | Frame Shift Del (DEL) | VAF 75/381 reads (20%) | called by pindel, varscan2*
- PIK3R6 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- POU3F2 | c.765C>G p.H255Q | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); called by muse, mutect2
- QRICH2 | c.2485C>G p.Q829E | Missense Mutation (SNP) | VAF 211/852 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SCUBE2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SOX9 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SWSAP1 | c.145_153del p.P49_G51del (on ENST00000312423; = p.P70_G72del on NM_175871.4) | In Frame Del (DEL) | VAF 22/147 reads (15%) | called by mutect2, pindel, varscan2
- THOC2 | c.2444T>G p.F815C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF410 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2
- ZNF43 | c.201G>T p.R67S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF606 | c.891_894del p.F298Ifs*3 | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | called by mutect2, pindel, varscan2
- ZNF701 | c.1534G>C p.V512L (on ENST00000301093; = p.V446L on NM_018260.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GBA3 | c.1311C>T p.H437= | Silent (SNP) | VAF 109/383 reads (28%) | catalogued as rs768836989; called by muse, mutect2, varscan2
- GNS | c.432C>T p.T144= | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- KAT8 | c.1017C>T p.L339= | Silent (SNP) | VAF 62/523 reads (12%) | called by muse, mutect2, varscan2
- MYO16 | c.3957C>T p.L1319= | Silent (SNP) | VAF 144/498 reads (29%) | catalogued as rs552539166; called by muse, mutect2
- NLRP4 | c.636C>T p.P212= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as rs771374690, COSV56712458; called by muse, mutect2, varscan2
- OR4F15 | c.753T>C p.F251= | Silent (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- PCDH17 | c.1065C>T p.S355= | Silent (SNP) | VAF 30/636 reads (5%) | catalogued as COSV64976855; called by muse, mutect2
- TUBB6 | c.87C>T p.G29= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs376972319, COSV58353987; called by muse, mutect2, varscan2
- VPS13C | c.9163C>T p.L3055= (on ENST00000644861 / NM_020821.3; = p.L3012= on NM_017684.5) | Silent (SNP) | VAF 8/232 reads (3%) | called by muse, mutect2
- AC002519.1 | chr16:31793798 G>A | 3'Flank (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- GABRE | c.785-1625C>G | Intron (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- LAIR1 | c.415+1461G>A | Intron (SNP) | VAF 22/91 reads (24%) | catalogued as rs772574844, COSV57306261; called by muse, mutect2, varscan2
- PRR12 | c.52-58C>T | Intron (SNP) | VAF 39/319 reads (12%) | catalogued as rs758770663; called by muse, mutect2, varscan2
- SH3TC1 | c.3131+314T>C | Intron (SNP) | VAF 87/297 reads (29%) | called by muse, mutect2, varscan2
- SPOCD1 | c.1869-33C>T | Intron (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
